CCDI case PBCGGM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/85e5464d-a5e7-41b0-88d3-4a60c57902a8

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 21.7 years (7,941 days).

Biospecimens (3 samples)
- Sample 0DRPIW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRPJ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRPJ7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
